Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3336, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3336-01A (Primary Tumor).

[page 1 of 2]
PATIENT INFORMATION

PHYSICIAN INFORMATION

SPECIMEN INFORMATION

Collected:

Received:

Reported:

Accession:

Acct / Reg:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Right kidney, radical nephrectomy:
Renal carcinoma.

Tumor Characteristics:

1. Histologic type: Clear cell carcinoma. ✓
2. Tumor site: Central aspect of kidney surrounding and distorting renal pelvis and calyces.
3. Tumor size: 4.5 cm in maximal diameter.
4. Macroscopic extent of tumor: Limited to kidney. ✓
5. Nuclear grade: Fuhrman grade: 4/4.
6. Lymphovascular space invasion: Not identified.
7. Transcapsular invasion: Not identified.
8. Renal vein invasion: Not identified.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not identified.

Surgical Margin Status:

1. Soft tissue margins: Negative for tumor.
2. Ureteral margin: Negative for tumor.
3. Vascular Margins: Negative for tumor.

Lymph Node Status: No lymph nodes identified.

Other Significant Findings:

1. pTNM stage: T1 NX MX, stage I.

Electronic Signature:

CLINICAL INFORMATION

[page 2 of 2]
PATIENT INFORMATION

SPECIMEN INFORMATION

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right kidney tumor

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right kidney.

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single container labeled with the patient's name [REDACTED] right kidney. The specimen consists of a previously bisected kidney with attached perinephric fat measuring in total 20.0 x 12.0 x 5.0 cm weighing 600 grams. The attached perinephric fat has been partially separated from the kidney exposing the capsule. The kidney itself measures 14.0 x 7.0 x 3.5 cm. The capsular surface is gray tan with slight hemorrhage. The capsule has been inked. The ureter is identified and measures 7.5 cm in length and 0.3 cm in diameter. The surface of the ureter is gray tan to brown tan with slight adhesions. The ureter is opened. The mucosal surface is gray tan. There are no lesions grossly identified. The renal pelvis and calices are however distorted and surrounded by a large gray tan friable yellow to brown tan mass measuring 4.5 x 4.5 x 3.0 cm. The mass appears grossly confined to the cortex and does not appear to invade through the capsule into the surrounding perinephric fat and is within and abuts the capsule surface. The surrounding renal cortex measures 0.5 cm and shows well demarcated renal pyramids and cortical junction. The renal artery vein and stump have been identified. The renal artery measures 0.5 cm in length and 0.3 cm in diameter and is grossly unremarkable. The renal vein stump measures 1.0 cm in length and 0.7 cm in diameter and is grossly unremarkable. There is no adrenal gland attached to the specimen.

Representative sections were taken for genomic studies and placed in orange cassettes labeled A through C. Received with the specimen are two cassettes one green and one yellow labeled [REDACTED]. Representative sections are submitted in cassette [REDACTED] as follows sections from mass in relationship to margin in blocks 1 and 2 additional sections from mass in blocks 3 and 4 sections from mass in relationship to the surrounding normal appearing kidney block 5 sections from surrounding kidney block 6 ureter block 7 renal artery and vein block 8.

END OF REPORT

Source: NCI Genomic Data Commons file 270f8e19-34de-4f96-8d9e-68dcbf572229 (TCGA-A3-3336.2B2F6CF4-675F-4A80-A712-B4D915E82104.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).